FM case AD15765 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/9be5f907-ea51-4f06-a64f-4dfce662a38e

Female, 62.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
